Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4VF, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4VF-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –
BENIGN ADIPOSE TISSUE.

PART 2: UTERUS WITH CERVIX, BILATERAL ADNEX, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL
SALPINGO-OOPHORECTOMY –

- A. MALIGNANT MIXED MULLERIAN TUMOR OF UTERUS.
- B. TWO (2) LARGE TUMORS MEASURING 8.5 X 5.2 AND 3.1 X 3.0 CM, RESPECTIVELY (GROSS MEASUREMENT).
- C. BOTH TUMORS SHOW POLYPOID GROWTH PATTERN WITH DEPTH OF MYOMETRIUM INVASION 35% (0.7 OF 2.0 CM, SLIDES K AND L).
- D. LYMPHOVASCULAR INVASION IS NOTED.
- E. CERVIX WITH SQUAMOUS METAPLASIA WITH NO TUMOR INVOLVEMENT.
- F. LEIOMYOMA (3.5 CM) AND ADENOMYOSIS.
- G. SURGICAL MARGINS ARE NEGATIVE FOR MALIGNANCY.
- H. LEFT AND RIGHT OVARIES WITH BENIGN SEROUS CYSTADENOFIBROMA.
- I. RIGHT FALLOPIAN TUBE WITH HYDROSALPINX.
- J. LEFT FALLOPIAN TUBE WITH PARATUBAL CYSTS.

PART 3: PELVIC LYMPH NODES, LEFT, BIOPSY –
THREE (3) LYMPH NODES, NEGATIVE FOR METASTATIC MALIGNANCY.

PART 4: PELVIC LYMPH NODE, RIGHT, BIOPSY –
ONE (1) LYMPH NODE, NEGATIVE FOR METASTATIC MALIGNANCY.

COMMENT:

Immunostains for vimentin, AE1/AE3 and cam 5.2 were performed on block 2E, 2M, 2O (desmin and caldesmon), confirming the diagnosis. The Malignant epithelial component includes endometrioid carcinoma and also undifferentiated carcinoma (slide 2E). Pelvic wash is negative for malignancy.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Carcinosarcoma (malignant mixed mesodermal tumor)

TUMOR SIZE: Maximum dimension: 8.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 60 %, Posterior endomyometrium: 90 %
Less than 1/2 thickness of myometrium

DEPTH OF INVASION**:

ANGIOLYMPHATIC INVASION:

Yes

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 4

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

ICD-O-3

Carcinosarcoma / Mixed Mullerian

Tumor, malignant 8950/3

Site: Corpus Uteri, endometrium
C54.1

Qx0 6/28/13

Staging Discrepancy		☒
Prognostic History		☒
Immunohistochemical Discrepancy		☒
Reviewed By: BHL	Date Review: 12/27/12	

Source: NCI Genomic Data Commons file 8e45542a-d279-4fd8-ab81-76d362cc63e5 (TCGA-N6-A4VF.621AF550-E9DE-403D-8F71-57830CBBEF22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).